Somatic mutation profile of tumor specimen C3N-03885-03 (aliquot CPT0221830006) from CPTAC case C3N-03885, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 32.7 years (11,945 days).
Specimen C3N-03885-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c83ba4cb-b729-48e9-a899-aea8fa6e9ffb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03885-71 (Blood Derived Normal), aliquot CPT0221930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c1d350a-63a7-4b49-99e5-ffe786fc67d0

The open-access MAF lists 3,289 somatic variants for this specimen: 2,089 protein-altering or splice-affecting, 1,087 silent, 113 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,924, Silent 1,087, Nonsense Mutation 122, Intron 65, Splice Region 23, 3'UTR 16, RNA 12, Splice Site 11, 5'Flank 11, Translation Start Site 6, 3'Flank 5, 5'UTR 4.

Variants (750 of 3,289; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 304/940 reads (32%) | catalogued as rs773948197; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CAPN3 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 172/567 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773001194, CM990305, COSV58820875; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 140/360 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs80356693, CM045135; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL2A1 | c.2035A>T p.K679* | Nonsense Mutation (SNP) | VAF 284/601 reads (47%) | catalogued as rs1565679039; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.2177G>A p.G726E | Missense Mutation (SNP) | VAF 343/418 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779698, CM1412591, COSV58595039; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH1 | c.12339G>A p.W4113* | Nonsense Mutation (SNP) | VAF 127/564 reads (23%) | catalogued as rs767196276; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 201/643 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LTBP2 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 322/778 reads (41%) | catalogued as rs137854855, CM126924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MOCOS | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 152/433 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750896617, CM071866, COSV54341815, COSV54346627; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 816/1110 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 380/484 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 313/591 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.327); catalogued as rs756313525; called by muse, mutect2, varscan2
- ABCA13 | c.5392C>T p.L1798F | Missense Mutation (SNP) | VAF 92/259 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV101329919, COSV70026471; called by muse, mutect2, varscan2
- ABCA13 | c.13709C>T p.S4570F | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68944042; called by muse, mutect2, varscan2
- ABCA4 | c.4720G>C p.E1574Q | Missense Mutation (SNP) | VAF 245/637 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as CM091659; called by muse, mutect2, varscan2
- ABCA4 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 214/548 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV100933268; called by muse, mutect2, varscan2
- ABCB5 | c.2546C>T p.A849V (on ENST00000404938 / NM_001163941.2; = p.A404V on NM_178559.6) | Missense Mutation (SNP) | VAF 194/489 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV51712089; called by muse, mutect2, varscan2
- ABCC1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 288/616 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs372116954; called by muse, mutect2, varscan2
- ABCC3 | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 453/598 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV53321363; called by muse, mutect2, varscan2
- ABL2 | c.2399C>T p.T800I (on ENST00000502732 / NM_007314.4; = p.T785I on NM_005158.5) | Missense Mutation (SNP) | VAF 91/494 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1459837769; called by muse, mutect2, varscan2
- AC099489.1 | c.4196G>C p.S1399T | Missense Mutation (SNP) | VAF 286/578 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as rs1355628269; called by muse, mutect2, varscan2
- ACAD10 | c.3014C>T p.S1005F | Missense Mutation (SNP) | VAF 279/545 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.398); catalogued as rs746451494; called by muse, mutect2, varscan2
- ACP3 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 164/337 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV60487570; called by muse, mutect2, varscan2
- ACTRT1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 295/357 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64419460, COSV64420243; called by muse, mutect2, varscan2
- ADAM15 | c.747C>T p.F249= | Splice Region (SNP) | VAF 110/637 reads (17%) | catalogued as COSV55125821, COSV55126633; called by muse, mutect2, varscan2
- ADAM2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs773158009, COSV55863118; called by muse, mutect2, varscan2
- ADAM7 | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV51535407; called by muse, mutect2, varscan2
- ADAMTS12 | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 112/282 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs774886665, COSV61274356; called by muse, mutect2, varscan2
- ADAMTS18 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.557); catalogued as rs1239818884; called by muse, varscan2
- ADAMTS19 | c.2251G>A p.G751R | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50749336; called by muse, mutect2, varscan2
- ADAMTS2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 160/655 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as rs763890617, COSV99200985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.4702G>A p.E1568K | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.767); catalogued as rs925998386, COSV67133124; called by muse, mutect2, varscan2
- ADAMTS3 | c.2206C>G p.P736A | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs199518563, COSV54387086; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 81/518 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.398); catalogued as COSV99717938; called by muse, mutect2, varscan2
- ADD2 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 359/695 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV52459970; called by muse, mutect2, varscan2
- ADGRE1 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 66/362 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as rs755844453, COSV51676264; called by muse, mutect2, varscan2
- ADGRL3 | c.1277C>T p.P426L (on ENST00000506720 / NM_001322402.2; = p.P358L on NM_015236.6) | Missense Mutation (SNP) | VAF 98/260 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72269486; called by muse, mutect2, varscan2
- ADGRV1 | c.11837G>A p.G3946E | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751526081; called by muse, mutect2, varscan2
- ADPRS | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 313/755 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs1188484640; called by muse, mutect2, varscan2
- ADRA1A | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 358/711 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV52358475; called by muse, mutect2, varscan2
- ADRM1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 526/1195 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.796); catalogued as rs1440336672; called by muse, mutect2, varscan2
- AFP | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.828); catalogued as COSV56925556; called by muse, mutect2, varscan2
- AGBL1 | c.2603C>T p.S868F | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV66872357; called by muse, mutect2, varscan2
- AIM2 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 80/474 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs760937015; called by mutect2, varscan2
- AKAP6 | c.3802C>T p.H1268Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV55226417; called by muse, mutect2, varscan2
- AKAP6 | c.4412C>T p.S1471L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs200742156, COSV55212711; called by muse, mutect2, varscan2
- AKNA | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 301/429 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1232269629, COSV56311959; called by muse, mutect2, varscan2
- AL592490.1 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as rs772808319; called by muse, mutect2, varscan2
- ALDH1A1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 106/145 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1352312729; called by muse, mutect2, varscan2
- AMACR | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 155/424 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs774180397, COSV56869642; called by muse, mutect2, varscan2
- AMPH | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 101/269 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781682680, COSV57737654; called by muse, mutect2, varscan2
- ANK1 | c.4885G>A p.D1629N | Missense Mutation (SNP) | VAF 387/743 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV55892171; called by muse, mutect2, varscan2
- ANK3 | c.7003G>A p.E2335K | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs769392075, COSV55047176; called by muse, mutect2, varscan2
- ANK3 | c.5824G>A p.E1942K | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); catalogued as rs963549742; called by muse, mutect2, varscan2
- ANK3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55044950; called by muse, mutect2, varscan2
- ANK3 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 154/400 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55048999; called by muse, varscan2
- ANK3 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 120/346 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs868365286, COSV55044904; called by muse, varscan2
- ANKRD11 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 400/783 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1385566000, COSV56359159; called by muse, mutect2, varscan2
- ANKRD28 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1285937135, COSV101080196; called by muse, mutect2, varscan2
- ANKRD45 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as COSV60960804; called by muse, mutect2, varscan2
- ANP32D | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 145/293 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs147147368, COSV56980271, COSV99874355; called by muse, mutect2, varscan2
- ANTXR1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774300710, COSV58013918; called by muse, mutect2, varscan2
- AP3B2 | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 181/559 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.646); catalogued as COSV55613414; called by muse, mutect2, varscan2
- AP5Z1 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 506/1158 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs768595771, COSV62242429; ClinVar: uncertain significance; called by muse, mutect2
- APOBEC1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.718); catalogued as COSV57550270; called by muse, mutect2, varscan2
- ARAP2 | c.4891C>T p.R1631W | Missense Mutation (SNP) | VAF 128/313 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs747621294, COSV58289982; called by muse, mutect2, varscan2
- ARID1A | c.5680C>T p.Q1894* | Nonsense Mutation (SNP) | VAF 322/741 reads (43%) | catalogued as COSV61374094; called by muse, mutect2, varscan2
- ARL14 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 224/497 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV57899802; called by muse, mutect2, varscan2
- ARL6IP1 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 142/434 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100435951; called by muse, mutect2, varscan2
- ARMC5 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 369/1169 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs747183399, CD1312676, COSV51655083, COSV51655149; called by muse, mutect2, varscan2
- ARMC5 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 244/745 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV51660119; called by muse, mutect2, varscan2
- ARRDC5 | c.697G>A p.E233K (on ENST00000381781; = p.E219K on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 339/814 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as rs372235175; called by muse, mutect2, varscan2
- ARSF | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 185/226 reads (82%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV63840039; called by muse, mutect2, varscan2
- ASB4 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1351518421, COSV57507750; called by muse, mutect2, varscan2
- ASPSCR1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 538/690 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs1277618403, COSV60730439; called by muse, mutect2, varscan2
- ASXL3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1461211700, COSV52458522, COSV99324388; called by muse, mutect2, varscan2
- ATAD3B | c.329C>T p.S110F (on ENST00000308647; = p.S216F on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 275/883 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs1484692742; called by muse, mutect2, varscan2
- ATG9B | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 294/714 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52503527; called by muse, varscan2
- ATP11C | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 125/143 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs768123444; called by muse, mutect2, varscan2
- ATP8B4 | c.3446G>A p.R1149Q | Missense Mutation (SNP) | VAF 62/385 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs145783329, COSV104371650; called by muse, mutect2, varscan2
- ATXN1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 525/671 reads (78%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55222114; called by muse, mutect2, varscan2
- AXIN1 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 268/861 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV51991769; called by muse, mutect2, varscan2
- BAG3 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 282/697 reads (40%) | catalogued as COSV64842012; called by muse, mutect2, varscan2
- BAIAP2L1 | c.807+1G>A p.X269_splice | Splice Site (SNP) | VAF 183/416 reads (44%) | catalogued as rs766225205; called by muse, mutect2, varscan2
- BARHL1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 262/363 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1348428858; called by muse, mutect2, varscan2
- BCAS3 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 253/322 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV66779801; called by muse, mutect2, varscan2
- BCL9L | c.2924C>T p.S975L | Missense Mutation (SNP) | VAF 397/539 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs147776799; called by muse, varscan2
- BICDL2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 205/612 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV54156447; called by muse, mutect2, varscan2
- BICRA | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 288/737 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1020829922; called by muse, mutect2, varscan2
- BIN1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 360/415 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs766894632, COSV52120226; called by muse, mutect2, varscan2
- BMP1 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 179/591 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as rs772641740; called by muse, mutect2, varscan2
- BPIFB4 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 273/729 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64951043; called by muse, mutect2, varscan2
- BPIFC | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 95/442 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV100301321; called by muse, mutect2, varscan2
- BRINP1 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 48/71 reads (68%) | catalogued as COSV56300506; called by muse, mutect2, varscan2
- BRINP3 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV66520060; called by muse, mutect2, varscan2
- BRIX1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs371167481; called by muse, mutect2, varscan2
- BRMS1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 223/282 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749417187; called by muse, mutect2, varscan2
- BSN | c.11366C>T p.P3789L | Missense Mutation (SNP) | VAF 151/785 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs757292234; called by muse, mutect2, varscan2
- BTBD8 | c.4055G>A p.R1352Q (on ENST00000636805 / NM_001376131.1; = p.R839Q on NM_015237.4) | Missense Mutation (SNP) | VAF 134/342 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.275); catalogued as rs373917273, COSV64883469; called by muse, mutect2, varscan2
- BTK | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 406/464 reads (88%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV58117474; called by muse, mutect2, varscan2
- C10orf120 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV61492603; called by muse, mutect2, varscan2
- C1QB | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 230/512 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV59244969; called by muse, mutect2, varscan2
- C1orf158 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 223/883 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.373); catalogued as rs1393249105; called by muse, mutect2, varscan2
- C1orf87 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs954642126, COSV64596002; called by muse, mutect2, varscan2
- C3 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 218/555 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs149906766; called by muse, mutect2, varscan2
- C7 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV57481875; called by muse, mutect2, varscan2
- C7 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1412761275, COSV100496778; called by muse, mutect2, varscan2
- C8A | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs11804257; called by muse, mutect2, varscan2
- C8B | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs773136580, COSV100980903; called by muse, mutect2, varscan2
- C8orf34 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 42/62 reads (68%) | catalogued as rs1378966968, COSV61392437; called by muse, mutect2, varscan2
- CA1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV56278260; called by muse, mutect2, varscan2
- CA13 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377312451; called by muse, mutect2, varscan2
- CABCOCO1 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs376865516; called by muse, mutect2, varscan2
- CABYR | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV59110602; called by muse, mutect2, varscan2
- CACNA1C | c.2948C>T p.S983F | Missense Mutation (SNP) | VAF 131/393 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59781616; called by muse, mutect2, varscan2
- CACNA2D3 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 187/318 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55562927; called by muse, mutect2, varscan2
- CACNA2D4 | c.2717G>A p.R906Q | Missense Mutation (SNP) | VAF 293/514 reads (57%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs189066664; called by muse, mutect2, varscan2
- CACNA2D4 | c.2568G>A p.M856I | Missense Mutation (SNP) | VAF 287/764 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1385257290; called by muse, mutect2, varscan2
- CACNA2D4 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 225/659 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54962385; called by muse, mutect2, varscan2
- CADPS | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 423/563 reads (75%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as COSV51869590; called by muse, mutect2, varscan2
- CADPS2 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV100462710; called by muse, mutect2, varscan2
- CALCR | c.928G>A p.E310K (on ENST00000649521 / NM_001164737.2; = p.E294K on NM_001742.4) | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV64012198; called by muse, mutect2, varscan2
- CALD1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 199/485 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs751236876; called by muse, mutect2, varscan2
- CAPN12 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 138/812 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs373317576; called by muse, mutect2
- CAPN8 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV64816209; called by muse, mutect2, varscan2
- CASR | c.2489G>A p.G830E (on ENST00000490131; = p.G907E on NM_000388.4) | Missense Mutation (SNP) | VAF 386/787 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV56134341, COSV56139655; called by muse, mutect2, varscan2
- CASS4 | c.1862C>T p.S621L | Missense Mutation (SNP) | VAF 313/818 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV64388024; called by muse, mutect2, varscan2
- CC2D2B | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs1253047317; called by muse, mutect2, varscan2
- CCDC141 | c.4457C>T p.S1486F | Missense Mutation (SNP) | VAF 159/207 reads (77%) | SIFT tolerated (0.1); PolyPhen benign (0.238); catalogued as COSV55383495; called by muse, mutect2, varscan2
- CCDC170 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 235/313 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1348980224, COSV53347165; called by muse, mutect2, varscan2
- CCDC27 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 679/1123 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs767500679; called by muse, mutect2, varscan2
- CCDC38 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV60183906; called by muse, mutect2, varscan2
- CCDC57 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 366/473 reads (77%) | catalogued as rs868862756; called by muse, mutect2, varscan2
- CCDC88C | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 351/914 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs1236996685, COSV101106249; called by muse, mutect2, varscan2
- CCKBR | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 376/656 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs138829785; called by muse, varscan2
- CCNA1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as COSV55224869; called by muse, mutect2, varscan2
- CCNO | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 197/392 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.132); catalogued as rs780164279; called by muse, mutect2, varscan2
- CD2AP | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 220/301 reads (73%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV63758966; called by muse, mutect2, varscan2
- CD93 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 367/784 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs267605854; called by muse, varscan2
- CDCP1 | c.1818G>A p.M606I | Missense Mutation (SNP) | VAF 358/624 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV56104028; called by muse, varscan2
- CDH6 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54078289; called by muse, mutect2, varscan2
- CDH6 | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV99418001; called by muse, varscan2
- CDH7 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV59884317; called by muse, mutect2, varscan2
- CDHR1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 181/457 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs770839275; called by muse, mutect2, varscan2
- CDHR5 | c.1835G>A p.G612E (on ENST00000358353 / NM_001171968.2; = p.G618E on NM_021924.5) | Missense Mutation (SNP) | VAF 533/1008 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV57642998; called by muse, mutect2, varscan2
- CELA1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 206/427 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV53332153; called by muse, mutect2, varscan2
- CEP152 | c.4912C>T p.P1638S (on ENST00000380950 / NM_001194998.2; = p.P1582S on NM_014985.4) | Missense Mutation (SNP) | VAF 132/421 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as COSV57863825; called by muse, mutect2, varscan2
- CFAP251 | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 220/708 reads (31%) | catalogued as rs1018120311, COSV56609735; called by muse, mutect2, varscan2
- CFAP46 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 167/367 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as COSV63949451, COSV63953211; called by muse, mutect2, varscan2
- CFAP54 | c.3040C>T p.L1014F | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1448231498; called by muse, mutect2, varscan2
- CFAP57 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 124/313 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV65264452; called by muse, mutect2, varscan2
- CFAP61 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 148/554 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs780648239; called by muse, mutect2, varscan2
- CFAP74 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 193/696 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1558065145; called by muse, mutect2, varscan2
- CFHR1 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 132/218 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV57628063; called by muse, mutect2, varscan2
- CHAT | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 268/658 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1165232739; called by muse, mutect2, varscan2
- CHRM3 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs759011572; called by muse, mutect2, varscan2
- CHRNA2 | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 181/565 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as rs755631456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST5 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 332/647 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs1458966951, COSV60337256; called by muse, mutect2, varscan2
- CIB2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 400/809 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs780146135; called by muse, mutect2, varscan2
- CIDEC | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 186/865 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1273518584; called by muse, mutect2, varscan2
- CLASP1 | c.4427C>T p.T1476I | Missense Mutation (SNP) | VAF 337/394 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760400075; called by muse, mutect2, varscan2
- CLCNKB | c.287G>A p.W96* | Nonsense Mutation (SNP) | VAF 194/739 reads (26%) | catalogued as COSV65160896; called by muse, mutect2, varscan2
- CLEC18B | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 252/1271 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs766840033; called by muse, mutect2, varscan2
- CLEC4D | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 176/348 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs932506883; called by muse, mutect2, varscan2
- CLTRN | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435868426; called by muse, mutect2, varscan2
- CNDP1 | c.759G>A p.V253= | Splice Region (SNP) | VAF 134/343 reads (39%) | catalogued as COSV62595605; called by muse, mutect2, varscan2
- CNGB1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 222/741 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.14); catalogued as rs761720019, COSV51904177; called by muse, mutect2, varscan2
- CNTN1 | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs373871151; called by muse, mutect2, varscan2
- CNTN2 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 315/556 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV59350893; called by muse, mutect2, varscan2
- CNTN5 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1279173094, COSV99671333; called by muse, mutect2, varscan2
- CNTN5 | c.3203G>A p.G1068E | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV54313248; called by muse, mutect2
- CNTNAP2 | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 135/772 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.038); catalogued as COSV100673085; called by muse, mutect2, varscan2
- CNTNAP3 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 194/268 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs140604792; called by muse, mutect2, varscan2
- COL11A1 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 158/290 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV100617686; called by muse, mutect2, varscan2
- COL11A1 | c.3740C>T p.S1247L | Missense Mutation (SNP) | VAF 94/448 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV62178157; called by muse, mutect2, varscan2
- COL12A1 | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 130/156 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1028351058; called by muse, mutect2, varscan2
- COL14A1 | c.4927C>T p.P1643S | Missense Mutation (SNP) | VAF 241/462 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV52860843; called by muse, mutect2, varscan2
- COL14A1 | c.5239C>T p.P1747S | Missense Mutation (SNP) | VAF 153/493 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV52853371; called by muse, mutect2, varscan2
- COL17A1 | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 180/460 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.196); catalogued as rs1012649359; called by muse, varscan2
- COL17A1 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 191/474 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62229873; called by muse, mutect2, varscan2
- COL23A1 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 233/452 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66792056, COSV66796797; called by muse, mutect2, varscan2
- COL4A3 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 375/453 reads (83%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV101170474; called by muse, mutect2, varscan2
- COL4A6 | c.2780G>A p.G927E | Missense Mutation (SNP) | VAF 304/351 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57859421, COSV57869363; called by muse, mutect2, varscan2
- COL6A3 | c.4735G>A p.D1579N | Missense Mutation (SNP) | VAF 553/661 reads (84%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs1164189369; called by muse, mutect2, varscan2
- COL6A6 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 230/524 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776380009; called by muse, mutect2, varscan2
- COL6A6 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 230/563 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1169902504; called by muse, mutect2, varscan2
- COPG1 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 129/392 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1387136273; called by muse, mutect2, varscan2
- CORO2A | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 208/290 reads (72%) | catalogued as rs201463123; called by muse, mutect2, varscan2
- CPAMD8 | c.1784C>T p.A595V (on ENST00000651564; = p.A548V on NM_015692.5) | Missense Mutation (SNP) | VAF 242/620 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs766613114; called by muse, mutect2, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 218/550 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2
- CPLANE2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 234/833 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs141168630; called by muse, mutect2, varscan2
- CPSF3 | c.117C>T p.L39= | Splice Region (SNP) | VAF 107/349 reads (31%) | catalogued as rs139906430; called by muse, mutect2, varscan2
- CR2 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889603; called by muse, mutect2, varscan2
- CRACD | c.3037C>T p.R1013C | Missense Mutation (SNP) | VAF 282/712 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as rs748479419; called by muse, mutect2, varscan2
- CRACDL | c.2836C>T p.L946F | Missense Mutation (SNP) | VAF 198/625 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1285591127; called by muse, mutect2, varscan2
- CRACR2A | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 258/805 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1466944166; called by muse, mutect2, varscan2
- CRACR2A | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 150/430 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs148809643; called by muse, mutect2, varscan2
- CRNN | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 420/741 reads (57%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV99664335; called by muse, mutect2, varscan2
- CROCC | c.2948C>T p.S983F | Missense Mutation (SNP) | VAF 207/562 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1231600904, COSV65011410; called by muse, mutect2, varscan2
- CRP | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs865849606, COSV54814632; called by muse, mutect2, varscan2
- CRTC3 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 189/401 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs762501027, COSV99185645; called by muse, mutect2, varscan2
- CRYBG1 | c.5701C>T p.R1901C | Missense Mutation (SNP) | VAF 218/284 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779661246; called by muse, mutect2, varscan2
- CRYBG2 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 264/702 reads (38%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.014); catalogued as rs375817247; called by muse, mutect2, varscan2
- CSF2RA | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 1242/1551 reads (80%) | SIFT tolerated (0.18); PolyPhen benign (0.13); catalogued as rs746550319; called by muse, varscan2
- CSMD1 | c.4232G>A p.G1411E (on ENST00000520002; = p.G1410E on NM_033225.6) | Missense Mutation (SNP) | VAF 121/382 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414213561; called by muse, mutect2, varscan2
- CSMD1 | c.2026C>T p.Q676* (on ENST00000520002; = p.Q675* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 158/312 reads (51%) | catalogued as rs1287947266, COSV100148827; called by muse, mutect2, varscan2
- CSMD2 | c.10361G>A p.R3454Q | Missense Mutation (SNP) | VAF 213/522 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as rs1431737649, COSV53907888, COSV99591312; called by muse, mutect2, varscan2
- CSPG4 | c.5911G>C p.D1971H | Missense Mutation (SNP) | VAF 143/908 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV57898943; called by muse, mutect2, varscan2
- CSPP1 | c.1540C>T p.P514S (on ENST00000676605; = p.P473S on NM_024790.6) | Missense Mutation (SNP) | VAF 194/589 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs371566997; called by muse, mutect2, varscan2
- CTAGE6 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 110/497 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV101417876; called by muse, mutect2, varscan2
- CTAGE9 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 320/469 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs1407869406; called by muse, mutect2, varscan2
- CTNNA2 | c.2783G>A p.R928Q (on ENST00000402739 / NM_001282597.3; = p.R880Q on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as rs766798712, COSV58158815; called by muse, mutect2, varscan2
- CUX1 | c.4388C>T p.P1463L | Missense Mutation (SNP) | VAF 352/834 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as rs782398565; called by muse, mutect2, varscan2
- CYP1A2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 211/592 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV59659574; called by muse, mutect2, varscan2
- CYP24A1 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 203/497 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259457397, COSV53777135; called by muse, mutect2, varscan2
- CYP2B6 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 187/521 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778199309; called by muse, mutect2, varscan2
- CYP2C8 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs775905230, COSV64876746; called by muse, mutect2
- CYP2E1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 147/371 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs958141259; called by muse, mutect2, varscan2
- CYP2F1 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 238/553 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV100462729; called by muse, mutect2, varscan2
- CYP4A22 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 126/431 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs138826010; called by muse, mutect2, varscan2
- CYP4B1 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 213/494 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV54724283; called by muse, mutect2, varscan2
- CYP4B1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 217/556 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs1487391289; called by muse, mutect2, varscan2
- CYP4F3 | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 170/473 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV55410505; called by muse, mutect2, varscan2
- CYP7B1 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as rs267601965, COSV59582493; called by muse, mutect2, varscan2
- DAZAP1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 211/529 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV51836308; called by muse, mutect2, varscan2
- DCAF5 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 268/650 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763891031; called by muse, mutect2, varscan2
- DCC | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV59081068, COSV59137171; called by muse, mutect2, varscan2
- DCDC1 | c.3836C>T p.A1279V (on ENST00000597505 / NM_001367979.1; = p.A386V on NM_020869.3) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1279960872; called by muse, mutect2, varscan2
- DCDC1 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV60853334; called by muse, mutect2, varscan2
- DDR2 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 56/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63372169; called by muse, mutect2, varscan2
- DDX43 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 281/376 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs541292561, COSV64836881; called by muse, mutect2, varscan2
- DDX60 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 155/353 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780613671, COSV67099939; called by muse, mutect2, varscan2
- DDX60 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 109/313 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV67100601; called by muse, mutect2, varscan2
- DDX60 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 118/325 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs758196490, COSV67094909; called by muse, varscan2
- DGKI | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 132/345 reads (38%) | catalogued as rs750429253, COSV55959948; called by muse, mutect2, varscan2
- DIRAS1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 317/837 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60215578; called by muse, mutect2, varscan2
- DISP3 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 212/858 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99608243; called by muse, mutect2, varscan2
- DLC1 | c.1810C>T p.P604S (on ENST00000276297 / NM_001348081.2; = p.P167S on NM_006094.5) | Missense Mutation (SNP) | VAF 497/955 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.084); catalogued as rs528860221, COSV52305409; called by muse, varscan2
- DLG2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.87); PolyPhen benign (0.03); catalogued as COSV54679067; called by muse, mutect2, varscan2
- DLGAP3 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 286/776 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1412135893, COSV52396015; called by muse, varscan2
- DLGAP3 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 139/709 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs754841934, COSV52397172; called by muse, mutect2, varscan2
- DNAH1 | c.9244C>T p.R3082C | Missense Mutation (SNP) | VAF 411/666 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs781114057, COSV70231260; called by muse, mutect2, varscan2
- DNAH14 | c.4498G>A p.G1500R (on ENST00000445597; = p.G1905R on NM_001367479.1) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357911055; called by muse, mutect2, varscan2
- DNAH14 | c.4645G>A p.D1549N (on ENST00000445597; = p.D1954N on NM_001367479.1) | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1415187709; called by muse, mutect2, varscan2
- DNAH5 | c.12631G>A p.E4211K | Missense Mutation (SNP) | VAF 199/509 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762673561, COSV54204698, COSV54216995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.11842G>A p.E3948K | Missense Mutation (SNP) | VAF 118/286 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV54229216; called by muse, mutect2, varscan2
- DNAH5 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV54202095, COSV54246376; called by muse, mutect2, varscan2
- DNAH6 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as rs750343141, COSV52863769; called by muse, varscan2
- DNAH7 | c.2657A>C p.D886A | Missense Mutation (SNP) | VAF 215/267 reads (81%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56771379; called by muse, mutect2, varscan2
- DNAH7 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 217/272 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV100415037, COSV56760037; called by muse, mutect2, varscan2
- DNAH7 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 99/116 reads (85%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56764153; called by muse, mutect2, varscan2
- DNASE1L2 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 427/790 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1182988190; called by muse, mutect2, varscan2
- DNM3 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62457191; called by muse, mutect2, varscan2
- DOCK10 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 289/334 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99290657; called by muse, mutect2, varscan2
- DOCK11 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 278/317 reads (88%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs765984589, COSV99353326; called by muse, mutect2, varscan2
- DOCK11 | c.4964G>A p.R1655Q | Missense Mutation (SNP) | VAF 193/228 reads (85%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); catalogued as rs368027571, COSV52233684; called by muse, mutect2, varscan2
- DPEP1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 360/687 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs368870164; called by muse, mutect2, varscan2
- DRC7 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 249/742 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs749727125; called by muse, mutect2, varscan2
- DSCAM | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 180/478 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68031995; called by muse, mutect2, varscan2
- DSG1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57134255; called by muse, mutect2, varscan2
- DSG4 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304709695, COSV57392050; called by muse, mutect2, varscan2
- DTHD1 | c.1732G>A p.D578N (on ENST00000456874; = p.D413N on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV62630458; called by muse, mutect2, varscan2
- DTX1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 175/535 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99986443; called by muse, mutect2, varscan2
- DTX3 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 185/646 reads (29%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.992); catalogued as rs758845062, COSV99677723; called by muse, mutect2, varscan2
- DUXB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 155/532 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as rs564936848; called by muse, mutect2, varscan2
- DYNC2H1 | c.9010C>T p.R3004C | Missense Mutation (SNP) | VAF 181/264 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752449341, CM1412957, COSV104398139; called by muse, mutect2, varscan2
- DYSF | c.4414G>A p.E1472K | Missense Mutation (SNP) | VAF 137/425 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.762); catalogued as COSV99245286; called by muse, mutect2, varscan2
- DZIP1L | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 198/452 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369290439, COSV59524030; called by muse, mutect2, varscan2
- EEF2K | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 408/795 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753635343, COSV53783886; called by muse, mutect2, varscan2
- EFCAB12 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 349/743 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs578026955; called by muse, mutect2, varscan2
- EFCAB6 | c.3370T>C p.Y1124H | Missense Mutation (SNP) | VAF 164/442 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1221405691, COSV53057898; called by muse, mutect2, varscan2
- EGR4 | c.1660G>A p.D554N (on ENST00000545030; = p.D451N on NM_001965.4) | Missense Mutation (SNP) | VAF 237/747 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761891593, COSV101474289; called by muse, mutect2, varscan2
- EHBP1L1 | c.3626C>T p.S1209F | Missense Mutation (SNP) | VAF 356/464 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs1278103516; called by muse, mutect2, varscan2
- EIF1B | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs927464483; called by muse, mutect2, varscan2
- EIF2S3B | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 188/643 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761096418; called by muse, mutect2, varscan2
- ELFN1 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 384/956 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.049); catalogued as rs1179124376; called by muse, mutect2, varscan2
- ELOA2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 250/582 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV55293823, COSV55302873; called by muse, mutect2, varscan2
- EMX1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 155/941 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99252391; called by muse, mutect2, varscan2
- ENPEP | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 208/472 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV54453550; called by muse, mutect2, varscan2
- ENPP3 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 197/270 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV100717052; called by muse, mutect2, varscan2
- EP400 | c.4459C>T p.P1487S | Missense Mutation (SNP) | VAF 150/526 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.059); catalogued as COSV57776391; called by muse, mutect2, varscan2
- EPB41L2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 176/235 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV61358997; called by muse, mutect2, varscan2
- EPB41L4A | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.849); catalogued as rs545808705, COSV54864767; called by muse, mutect2, varscan2
- EPB41L4A | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV54865906, COSV54878003; called by muse, mutect2, varscan2
- EPHA1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 322/836 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1287321074, COSV99314239; called by muse, mutect2, varscan2
- EPHA3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV60702358; called by muse, mutect2, varscan2
- EPPK1 | c.4751G>A p.R1584K | Missense Mutation (SNP) | VAF 443/895 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782559181, COSV73260833; called by muse, mutect2, varscan2
- EPPK1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 518/1030 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs545014988, COSV101599789, COSV73260886; called by muse, mutect2, varscan2
- ERBB4 | c.3419G>A p.S1140N | Missense Mutation (SNP) | VAF 258/316 reads (82%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100726322, COSV104418389; called by muse, mutect2, varscan2
- ERICH3 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs778330322, COSV58600851; called by muse, mutect2, varscan2
- ERN2 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 252/552 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99892150; called by muse, mutect2, varscan2
- ERV3-1 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 101/289 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1046229795, COSV99275846; called by muse, mutect2, varscan2
- ERV3-1 | c.827T>C p.F276S | Missense Mutation (SNP) | VAF 128/348 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs764801792; called by muse, varscan2
- ERVMER34-1 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 160/384 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as rs768531057; called by muse, varscan2
- ESR2 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 187/446 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1431061432, COSV50829496; called by muse, mutect2, varscan2
- EXD1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 247/497 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV59256437; called by muse, mutect2, varscan2
- EXOC3L1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 183/617 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as rs1411053465, COSV52046783; called by muse, mutect2, varscan2
- EYA1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD082096; called by muse, mutect2, varscan2
- F11 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 111/316 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53002396; called by muse, varscan2
- FAM133A | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs935098581, COSV59075900; called by muse, mutect2, varscan2
- FAM171B | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs776693409; called by muse, mutect2, varscan2
- FAM20C | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 386/981 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV58236507; called by muse, mutect2, varscan2
- FAM220A | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 331/757 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1195286966, COSV57627495; called by muse, mutect2, varscan2
- FAM227A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 487/793 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1452427974, COSV100874750; called by muse, mutect2, varscan2
- FAM71B | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 285/567 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100262071; called by muse, mutect2, varscan2
- FAM71E2 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 251/641 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV52772340; called by muse, mutect2, varscan2
- FAT1 | c.8488C>T p.Q2830* | Nonsense Mutation (SNP) | VAF 179/498 reads (36%) | catalogued as COSV71673183; called by muse, mutect2, varscan2
- FAT3 | c.7945G>A p.D2649N | Missense Mutation (SNP) | VAF 83/123 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1162671325, COSV53088584; called by muse, mutect2, varscan2
- FAT4 | c.8059C>T p.R2687* | Nonsense Mutation (SNP) | VAF 68/150 reads (45%) | catalogued as COSV58711961; called by muse, varscan2
- FBP2 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 166/211 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0.144); catalogued as COSV64694689; called by muse, mutect2, varscan2
- FBXL7 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 164/368 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV61641400; called by muse, mutect2, varscan2
- FBXO39 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 280/376 reads (74%) | SIFT tolerated (0.22); PolyPhen benign (0.397); catalogued as rs756968972, COSV58620957; called by muse, mutect2, varscan2
- FCRL3 | c.1245C>A p.Y415* | Nonsense Mutation (SNP) | VAF 143/333 reads (43%) | catalogued as COSV100943458; called by muse, mutect2, varscan2
- FCRL5 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 118/250 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100708724; called by muse, mutect2, varscan2
- FER1L5 | c.4756G>A p.D1586N (on ENST00000623019; = p.D1559N on NM_001293083.2) | Missense Mutation (SNP) | VAF 226/645 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750545075, COSV67606103; called by muse, mutect2, varscan2
- FGA | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 126/308 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1217351133; called by muse, mutect2, varscan2
- FGD3 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 338/486 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs1284098383; called by muse, mutect2, varscan2
- FGF21 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 273/639 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs1240408972, COSV55811158; called by muse, mutect2, varscan2
- FLG | c.5257G>A p.G1753S | Missense Mutation (SNP) | VAF 504/1015 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1443288957; called by muse, mutect2, varscan2
- FLG | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 402/833 reads (48%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.94); catalogued as rs749798893; called by muse, mutect2, varscan2
- FLG2 | c.4538G>A p.G1513D | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101165951, COSV66171314; called by muse, mutect2
- FLG2 | c.4537G>A p.G1513S | Missense Mutation (SNP) | VAF 42/371 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV66173991; called by muse, mutect2
- FLNC | c.2392G>A p.D798N | Missense Mutation (SNP) | VAF 160/404 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs778594252; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLRT2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368225812, COSV58140215; called by muse, mutect2, varscan2
- FLT1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766489043, COSV56724787; called by muse, mutect2, varscan2
- FLT4 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 128/510 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs199942873, COSV56123360; called by muse, mutect2, varscan2
- FMN2 | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); catalogued as COSV60428568, COSV60448956; called by muse, varscan2
- FOXD4L3 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 97/181 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1554670747; called by muse, mutect2, varscan2
- FOXP2 | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV63482706; called by muse, mutect2, varscan2
- FPR1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 209/526 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs376781635, COSV59051148; called by muse, varscan2
- FRAS1 | c.7085G>A p.R2362Q | Missense Mutation (SNP) | VAF 101/308 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs865839705, COSV53631054; ClinVar: uncertain significance; called by muse, varscan2
- FREM1 | c.4748G>A p.G1583E | Missense Mutation (SNP) | VAF 152/224 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs756235364; called by muse, mutect2, varscan2
- FREM2 | c.1852C>G p.P618A | Missense Mutation (SNP) | VAF 136/473 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54834118; called by muse, mutect2, varscan2
- FREM3 | c.3700G>A p.A1234T | Missense Mutation (SNP) | VAF 150/359 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs1385971434; called by muse, mutect2, varscan2
- FRMPD2 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 143/411 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs149092560; called by muse, mutect2, varscan2
- FSIP1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 190/388 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as rs1363704414, COSV63226886; called by muse, mutect2, varscan2
- FSTL5 | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60188547; called by muse, mutect2, varscan2
- FUT5 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 218/748 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.711); catalogued as rs1329828365, COSV53136423; called by muse, mutect2
- GAA | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 297/374 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs760277240; called by muse, mutect2, varscan2
- GABRG3 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 250/560 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV61510850, COSV61526145; called by muse, mutect2, varscan2
- GABRP | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV54662850; called by muse, mutect2, varscan2
- GALNT10 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561653928; called by muse, mutect2, varscan2
- GALNTL5 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 139/308 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV67179909, COSV67180148; called by muse, mutect2, varscan2
- GDF10 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 317/872 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199534890; called by muse, mutect2, varscan2
- GFRAL | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.936); catalogued as rs1562053089, COSV61229102; called by muse, mutect2, varscan2
- GHR | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1241437411, COSV50119804; called by muse, varscan2
- GKN1 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145664731; called by muse, mutect2, varscan2
- GLI1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 198/684 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs774058977, COSV57358829; called by muse, mutect2, varscan2
- GLIS1 | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 291/670 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.672); catalogued as rs539985102; called by muse, mutect2, varscan2
- GLIS3 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 212/290 reads (73%) | SIFT tolerated (0.62); PolyPhen benign (0.219); catalogued as rs765418117; called by muse, mutect2, varscan2
- GLP2R | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 140/194 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1048676889; called by muse, mutect2, varscan2
- GLRA1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs865940611, COSV51028119; called by muse, mutect2, varscan2
- GLRB | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV52412919; called by muse, mutect2, varscan2
- GNAO1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 250/464 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.111); catalogued as COSV52614612; called by muse, mutect2, varscan2
- GNS | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 156/517 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs769055154, COSV50693904; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 312/1794 reads (17%) | SIFT deleterious, low confidence (0.04); catalogued as rs1275566970; called by muse, mutect2
- GOLGA6L2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 131/389 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs758187935; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 366/932 reads (39%) | SIFT tolerated (0.06); catalogued as rs546787903; called by muse, varscan2
- GOLGA8S | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs1371298470; called by mutect2, varscan2
- GPM6A | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 114/342 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54531787, COSV54565099; called by muse, mutect2, varscan2
- GPR141 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs150971296; called by muse, mutect2, varscan2
- GPR20 | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 562/1065 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs766191335; called by muse, mutect2, varscan2
- GPR39 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 478/551 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61428641; called by muse, mutect2, varscan2
- GPR65 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1284265439; called by muse, mutect2, varscan2
- GRID1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs759000389, COSV60035054; called by muse, mutect2, varscan2
- GRID2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 119/311 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754110902, COSV56172424; called by muse, mutect2, varscan2
- GRIN2A | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 248/537 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs61758996, COSV58024168; ClinVar: benign; called by muse, mutect2, varscan2
- GRIN3A | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.313); catalogued as rs868754210; called by muse, varscan2
- GRM8 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 174/423 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58833155; called by muse, mutect2, varscan2
- GRM8 | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 51/227 reads (22%) | catalogued as rs199524891; called by muse, mutect2
- GTF3C2 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 256/505 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.335); catalogued as rs202111307; called by muse, mutect2, varscan2
- GUCA1C | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 94/146 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53751486, COSV99659838; called by muse, mutect2, varscan2
- GUCY2C | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99663213, COSV99663552; called by muse, mutect2, varscan2
- HCAR1 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 160/889 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs746134682; called by muse, mutect2, varscan2
- HCN1 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 224/564 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1477444033, COSV100301983, COSV57520811; called by muse, mutect2, varscan2
- HCN1 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV57522708, COSV57536689; called by muse, mutect2, varscan2
- HDC | c.1197A>C p.E399D | Missense Mutation (SNP) | VAF 185/580 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs374512383; called by muse, mutect2, varscan2
- HGF | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV55947254; called by muse, mutect2, varscan2
- HGFAC | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 354/824 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs140025700; called by muse, varscan2
- HHIPL2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 254/459 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58564422; called by muse, mutect2, varscan2
- HMGCS2 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 120/350 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs749020250; called by muse, mutect2, varscan2
- HNRNPA1P48 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 106/371 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as rs1392890668; called by muse, varscan2
- HNRNPCL2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 172/382 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV60403318; called by muse, mutect2, varscan2
- HPSE2 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 272/652 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as rs771343217; called by muse, mutect2, varscan2
- HTR2A | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV101096887; called by muse, mutect2, varscan2
- HTR4 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated, low confidence (0.61); PolyPhen probably damaging (0.956); catalogued as rs747707642, COSV58800362, COSV99042223; called by muse, mutect2, varscan2
- HYDIN | c.9904G>A p.D3302N | Missense Mutation (SNP) | VAF 353/734 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs773404736, COSV66881391; called by muse, mutect2, varscan2
- HYDIN | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs113898693, COSV55479229; called by muse, mutect2, varscan2
- IFI44L | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.346); catalogued as rs994770655; called by muse, mutect2, varscan2
- IGF2BP1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 136/455 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs867424326, COSV51729521, COSV51730080; called by muse, mutect2, varscan2
- IGFN1 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 428/699 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs562864069, COSV55169316; called by muse, mutect2, varscan2
- IGHV3-7 | c.26T>G p.F9C | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs782771849; called by muse, mutect2, varscan2
- IGLV4-60 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 133/505 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV66503452; called by muse, mutect2, varscan2
- IGSF21 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 179/463 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52126546; called by muse, mutect2, varscan2
- IL18RAP | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 164/584 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs753970829; called by muse, mutect2, varscan2
- IL1R2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 410/800 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as COSV60209619; called by muse, mutect2, varscan2
- IL31RA | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 106/471 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV61692543; called by muse, mutect2, varscan2
- IL36G | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 233/314 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99381132; called by muse, mutect2, varscan2
- IL5RA | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 211/357 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as rs1181103089, COSV56521545; called by muse, mutect2, varscan2
- INSRR | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 324/954 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100948068; called by muse, mutect2, varscan2
- IPO8 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 190/386 reads (49%) | catalogued as COSV56240527; called by muse, mutect2, varscan2
- IQSEC3 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 436/900 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1415185889; called by muse, varscan2
- IRAG2 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1309185188; called by muse, varscan2
- IRF6 | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 104/471 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as CD133895; called by muse, mutect2, varscan2
- IRF6 | c.301A>G p.K101E | Missense Mutation (SNP) | VAF 103/471 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV65419809; called by muse, mutect2, varscan2
- ITPR1 | c.6664G>A p.E2222K (on ENST00000354582; = p.E2167K on NM_002222.7) | Missense Mutation (SNP) | VAF 85/437 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV100232522; called by muse, mutect2, varscan2
- ITPRID1 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1405509762; called by muse, mutect2, varscan2
- IWS1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 184/220 reads (84%) | catalogued as COSV54871808; called by muse, mutect2, varscan2
- JAKMIP2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs757613667; called by muse, mutect2, varscan2
- JAKMIP3 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 180/443 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.436); catalogued as COSV100059226; called by muse, mutect2, varscan2
- KALRN | c.6361G>A p.G2121R (on ENST00000360013 / NM_001024660.4; = p.G424R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/509 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52250071; called by muse, mutect2, varscan2
- KANK4 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 228/638 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs141263563; called by muse, mutect2, varscan2
- KANSL3 | c.2410C>T p.R804C (on ENST00000666923 / NM_001349262.2; = p.R778C on NM_001115016.3) | Missense Mutation (SNP) | VAF 236/806 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs368507889; called by muse, mutect2, varscan2
- KAT8 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 352/701 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV54899779; called by muse, varscan2
- KCNA3 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 231/874 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901187; called by muse, mutect2, varscan2
- KCNB2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 237/484 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.298); catalogued as COSV73048997, COSV73049326; called by muse, mutect2, varscan2
- KCNC2 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.012); catalogued as COSV54383000; called by muse, mutect2, varscan2
- KCND1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 407/469 reads (87%) | catalogued as rs1311965120, COSV54413742; called by muse, mutect2, varscan2
- KCNIP2 | c.334C>T p.R112W (on ENST00000356640 / NM_173191.3; = p.R127W on NM_014591.5) | Missense Mutation (SNP) | VAF 121/310 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99493577; called by muse, varscan2
- KCNJ10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 396/644 reads (61%) | SIFT tolerated (0.63); PolyPhen benign (0.268); catalogued as rs200054482, COSV100927944; called by muse, varscan2
- KCNJ11 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 152/664 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs758749160, CM131725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ6 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 220/571 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762020565; called by muse, mutect2, varscan2
- KCNJ8 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 104/365 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.253); catalogued as COSV53715759, COSV53717400, COSV99557671; called by muse, mutect2, varscan2
- KCNK9 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 141/741 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57283108; called by muse, mutect2, varscan2
- KCNMB3 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 240/696 reads (34%) | catalogued as rs1302383597; called by muse, mutect2, varscan2
- KCNQ4 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 323/808 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1169737103; called by muse, mutect2, varscan2
- KCTD16 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV72579265; called by muse, mutect2, varscan2
- KDM6B | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 371/468 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as rs772320061, COSV54681109, COSV99642514; called by muse, mutect2, varscan2
- KHNYN | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 377/979 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs777610443; called by muse, mutect2, varscan2
- KHNYN | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 375/970 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.916); catalogued as rs1369254414; called by muse, mutect2, varscan2
- KIAA1217 | c.5755C>T p.P1919S | Missense Mutation (SNP) | VAF 93/394 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757982787; called by muse, mutect2, varscan2
- KIAA1328 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1226698827; called by muse, mutect2, varscan2
- KIAA1671 | c.4136C>T p.S1379F | Missense Mutation (SNP) | VAF 288/1233 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as rs1336841339; called by muse, mutect2, varscan2
- KIF20B | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 113/308 reads (37%) | catalogued as rs571660825; called by muse, mutect2, varscan2
- KIF26B | c.4478G>T p.S1493I | Missense Mutation (SNP) | VAF 613/1016 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100833098; called by muse, mutect2, varscan2
- KIF26B | c.5318C>T p.S1773L | Missense Mutation (SNP) | VAF 222/1042 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748915660; called by muse, mutect2, varscan2
- KIF2C | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 159/491 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775372478; called by muse, mutect2, varscan2
- KIF6 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 317/400 reads (79%) | SIFT tolerated (0.81); PolyPhen benign (0.018); catalogued as COSV54668654; called by muse, mutect2, varscan2
- KIR3DL3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 434/1661 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1277875430, COSV52550084; called by muse, mutect2
- KLHDC7A | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 286/765 reads (37%) | catalogued as COSV68769506; called by muse, mutect2, varscan2
- KLHL1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV100918406; called by muse, mutect2, varscan2
- KLHL34 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 176/432 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1384855904, COSV65279077; called by muse, mutect2, varscan2
- KLK10 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 358/838 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs767124161; called by muse, mutect2
- KLK3 | c.743A>C p.H248P | Missense Mutation (SNP) | VAF 233/519 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs927203347; called by muse, mutect2, varscan2
- KLK7 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 232/572 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58344594; called by muse, mutect2, varscan2
- KLRD1 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 172/322 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60274149; called by muse, mutect2, varscan2
- KMT2A | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 118/165 reads (72%) | catalogued as COSV63289880; called by muse, mutect2, varscan2
- KNDC1 | c.5099C>T p.S1700L | Missense Mutation (SNP) | VAF 203/524 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1331639413; called by muse, mutect2, varscan2
- KRT12 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 248/301 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52432324; called by muse, mutect2, varscan2
- KRT4 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 196/653 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs774011441; called by muse, varscan2
- KRT5 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 121/388 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs756254239; called by muse, varscan2
- KRT72 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 512/970 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV53374985; called by muse, mutect2, varscan2
- KRT84 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 191/735 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs774636253, COSV57771217; called by muse, mutect2, varscan2
- KRTAP12-1 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 255/680 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV59962192; called by muse, mutect2, varscan2
- KY | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 239/695 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as rs745454524; called by muse, mutect2, varscan2
- L3MBTL1 | c.1317G>A p.M439I (on ENST00000418998 / NM_001377303.1; = p.M349I on NM_015478.7) | Missense Mutation (SNP) | VAF 292/934 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1376940112, COSV64229212; called by muse, mutect2, varscan2
- L3MBTL2 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 484/742 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV53432587; called by muse, mutect2, varscan2
- LAMA1 | c.9104C>T p.S3035L | Missense Mutation (SNP) | VAF 98/473 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs147708500; called by muse, varscan2
- LAMA1 | c.7925C>T p.S2642L | Missense Mutation (SNP) | VAF 194/460 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.297); catalogued as rs761176408, COSV67534774, COSV67544997; called by muse, mutect2, varscan2
- LAMA2 | c.3478C>T p.P1160S | Missense Mutation (SNP) | VAF 265/371 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70350486; called by muse, mutect2, varscan2
- LAMA3 | c.6115C>T p.R2039C (on ENST00000313654 / NM_198129.4; = p.R430C on NM_000227.6) | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs138451075; called by muse, mutect2, varscan2
- LEPR | c.698A>T p.N233I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1459344809; called by muse, mutect2, varscan2
- LGALS16 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 101/284 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.296); catalogued as COSV104431295; called by muse, mutect2, varscan2
- LGR5 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 139/325 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs146135159, COSV57007618; called by muse, mutect2, varscan2
- LILRA1 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 224/673 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs772909436; called by muse, mutect2, varscan2
- LILRA5 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 328/838 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1446683336; called by muse, mutect2, varscan2
- LIN7A | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1565900469, COSV54019676; called by muse, mutect2, varscan2
- LIN9 | c.712C>T p.R238W (on ENST00000366808 / NM_001270410.2; = p.R183W on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 166/275 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60243760, COSV60246891; called by muse, mutect2, varscan2
- LMF1 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 293/855 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs764868188; called by muse, mutect2, varscan2
- LMX1A | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 90/462 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs759331204, COSV54218097, COSV54227124; called by muse, mutect2, varscan2
- LONRF2 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 154/479 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs754789376; called by muse, mutect2, varscan2
- LPA | c.4238C>T p.S1413L | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.727); catalogued as rs759479249; called by muse, mutect2, varscan2
- LPA | c.3994C>T p.P1332S | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1450704075; called by muse, mutect2, varscan2
- LPAR2 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 114/486 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV99179445; called by muse, mutect2, varscan2
- LPCAT1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 287/771 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs753194354; called by muse, mutect2, varscan2
- LRBA | c.6392G>A p.G2131E | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63957406; called by muse, mutect2, varscan2
- LRFN5 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 139/364 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV53243984; called by muse, mutect2, varscan2
- LRFN5 | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 176/382 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53261313, COSV99985710; called by muse, mutect2, varscan2
- LRIT1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 176/526 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV64512731; called by muse, mutect2, varscan2
- LRP1B | c.10792G>A p.E3598K | Missense Mutation (SNP) | VAF 57/63 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101261094; called by muse, mutect2, varscan2
- LRRC37A3 | c.4846G>A p.E1616K | Missense Mutation (SNP) | VAF 202/256 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs1380244997; called by muse, mutect2, varscan2
- LRRC4B | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 290/727 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as rs986834413; called by muse, mutect2, varscan2
- LRRFIP1 | c.1144C>T p.P382S (on ENST00000392000 / NM_001137552.2; = p.P358S on NM_004735.4) | Missense Mutation (SNP) | VAF 456/554 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs1483404122; called by muse, mutect2, varscan2
- LRRIQ1 | c.3479C>T p.S1160L | Missense Mutation (SNP) | VAF 170/476 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101279850; called by muse, mutect2, varscan2
- LRRK1 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 286/599 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as rs1264026847, COSV52602458; called by muse, mutect2, varscan2
- LRRTM1 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 264/858 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.081); catalogued as rs756907531, COSV54442831; called by muse, mutect2, varscan2
- LRTM1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 262/447 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV55558253; called by muse, mutect2, varscan2
- LRTM2 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 405/815 reads (50%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs752381627, COSV54566246; called by muse, mutect2, varscan2
- LRTM2 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 163/559 reads (29%) | catalogued as COSV54566211; called by muse, mutect2, varscan2
- LSM11 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 108/468 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1266481104; called by muse, mutect2, varscan2
- LSP1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 269/504 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs201040841, COSV61134142; called by muse, mutect2, varscan2
- MAB21L3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 105/352 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.112); catalogued as rs1412274180, COSV65673801; called by muse, mutect2, varscan2
- MACF1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 245/520 reads (47%) | catalogued as COSV58369638; called by muse, mutect2, varscan2
- MAGEL2 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 307/929 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as rs1296427095; called by muse, mutect2, varscan2
- MALRD1 | c.5543C>T p.T1848M | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as rs563984099; called by muse, mutect2, varscan2
- MAP1A | c.2696C>T p.S899F | Missense Mutation (SNP) | VAF 396/777 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746403493; called by muse, mutect2, varscan2
- MAP3K13 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 142/463 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.416); catalogued as COSV99034875; called by muse, mutect2, varscan2
- MARCHF11 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 180/444 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60126559; called by muse, mutect2, varscan2
- MARK4 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 256/589 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534682723, COSV53463698; called by muse, mutect2, varscan2
- MAS1 | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 249/347 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV53121571; called by muse, mutect2, varscan2
- MASP1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 297/604 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139378189; called by muse, mutect2, varscan2
- MATK | c.1271C>T p.P424L (on ENST00000310132 / NM_139355.3; = p.P425L on NM_002378.4) | Missense Mutation (SNP) | VAF 221/611 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940855145; called by muse, mutect2, varscan2
- MATN4 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 119/883 reads (13%) | catalogued as COSV59214079; called by muse, mutect2, varscan2
- MBTD1 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 148/192 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs776267329, COSV64503191; called by muse, mutect2, varscan2
- MDGA2 | c.2398C>T p.R800C (on ENST00000399232 / NM_001113498.2; = p.R502C on NM_182830.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776310493, COSV62078486; called by muse, mutect2, varscan2
- MECOM | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs1474588403; called by muse, mutect2, varscan2
- MEF2C | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 147/292 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV60937656; called by muse, mutect2, varscan2
- METTL24 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 237/309 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314425535; called by muse, mutect2, varscan2
- MGAM | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV101516514; called by muse, mutect2, varscan2
- MGAM | c.4333C>T p.P1445S | Missense Mutation (SNP) | VAF 207/512 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs3087313; called by muse, mutect2, varscan2
- MGAM2 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 146/323 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563264124; called by muse, mutect2, varscan2
- MMP13 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV52824829; called by muse, mutect2, varscan2
- MMP21 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 352/841 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs777814529; called by muse, mutect2, varscan2
- MNDA | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751266784, COSV63740840; called by muse, mutect2, varscan2
- MORC1 | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs866650943, COSV51721626; called by muse, varscan2
- MORC1 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs549951203, COSV51714451; called by muse, varscan2
- MORN1 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 350/1239 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66002681; called by muse, mutect2, varscan2
- MOV10L1 | c.3086G>A p.G1029E | Missense Mutation (SNP) | VAF 259/1050 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99433565; called by muse, mutect2, varscan2
- MPV17L | c.434C>T p.P145L (on ENST00000396385 / NM_001128423.2; = p.S121= on NM_173803.4) | Missense Mutation (SNP) | VAF 256/760 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55009004; called by muse, varscan2
- MRO | c.736A>C p.K246Q | Missense Mutation (SNP) | VAF 137/297 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761957945; called by muse, mutect2, varscan2
- MROH2B | c.3695G>A p.W1232* | Nonsense Mutation (SNP) | VAF 130/345 reads (38%) | catalogued as rs1181510194; called by muse, mutect2, varscan2
- MROH2B | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV68189450; called by muse, mutect2, varscan2
- MROH9 | c.1734G>A p.K578= | Splice Region (SNP) | VAF 51/209 reads (24%) | catalogued as rs554915861; called by muse, mutect2, varscan2
- MSH6 | c.1618C>A p.L540I | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs201996928, COSV52286461; ClinVar: uncertain significance; called by mutect2, varscan2
- MSMO1 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 120/337 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1273172497, COSV54971155; called by muse, mutect2, varscan2
- MTA2 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 337/439 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs769221329, COSV53468524; called by muse, mutect2, varscan2
- MTA3 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 178/381 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs761809163; called by muse, mutect2, varscan2
- MTERF1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 130/324 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs752117598, COSV100699533; called by muse, mutect2, varscan2
- MTMR8 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as rs750507967, COSV66392609; called by muse, mutect2, varscan2
- MTUS2 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 201/450 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV70919019; called by muse, mutect2, varscan2
- MTUS2 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 185/416 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV101462289, COSV101462366; called by muse, varscan2
- MUC12 | c.12187G>A p.E4063K (on ENST00000379442; = p.E3920K on NM_001164462.1) | Missense Mutation (SNP) | VAF 96/1891 reads (5%) | SIFT tolerated (0.12); catalogued as rs750395168; called by muse, mutect2
- MUC12 | c.13355C>T p.S4452L (on ENST00000379442; = p.S4309L on NM_001164462.1) | Missense Mutation (SNP) | VAF 104/1640 reads (6%) | SIFT deleterious (0); catalogued as rs777696015; called by muse, mutect2
- MUC16 | c.29969G>A p.R9990K | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.065); catalogued as COSV101200386, COSV67492792; called by muse, mutect2, varscan2
- MUC16 | c.27625G>A p.E9209K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); catalogued as COSV67478186; called by muse, mutect2, varscan2
- MUC16 | c.25780C>T p.L8594F | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV67447006, COSV67469286; called by muse, mutect2, varscan2
- MUC16 | c.24392G>C p.G8131A | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV67479047; called by muse, mutect2, varscan2
- MUC16 | c.23225C>T p.S7742L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as COSV67446858; called by muse, varscan2
- MUC16 | c.13640C>T p.S4547L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.569); catalogued as COSV101202017, COSV67488515; called by muse, mutect2, varscan2
- MUC16 | c.5069G>A p.G1690E | Missense Mutation (SNP) | VAF 110/213 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1302484021, COSV101199304; called by muse, mutect2, varscan2
- MUC16 | c.2654G>A p.R885K | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1195044971, COSV101199496; called by muse, mutect2, varscan2
- MUC16 | c.1442G>A p.R481K | Missense Mutation (SNP) | VAF 192/504 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.094); catalogued as rs760649210, COSV101198463; called by muse, mutect2, varscan2
- MUC17 | c.2888C>T p.S963L | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs1371676392, COSV60281001; called by muse, mutect2, varscan2
- MUC17 | c.6943G>A p.E2315K | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as COSV60282532; called by muse, mutect2, varscan2
- MUC17 | c.8419G>A p.E2807K | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs1210252753; called by muse, mutect2, varscan2
- MUC17 | c.9019C>T p.L3007F | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.86); catalogued as COSV100071552; called by muse, mutect2, varscan2
- MUC17 | c.9325G>A p.G3109S | Missense Mutation (SNP) | VAF 133/313 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.112); catalogued as rs201212959, COSV60293261; called by muse, mutect2, varscan2
- MUC17 | c.11320C>T p.P3774S | Missense Mutation (SNP) | VAF 175/403 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs771529320; called by muse, mutect2, varscan2
- MUC4 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 348/961 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs1156274343; called by muse, mutect2, varscan2
- MUC5B | c.16066G>A p.D5356N | Missense Mutation (SNP) | VAF 112/425 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs1564952568; called by muse, mutect2, varscan2
- MUC7 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 237/597 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); catalogued as rs866490673, COSV59217838, COSV59220184; called by muse, mutect2, varscan2
- MYCBP2 | c.10456C>T p.R3486W (on ENST00000357337; = p.R3524W on NM_015057.5) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100631279; called by muse, mutect2, varscan2
- MYCT1 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 73/98 reads (74%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs773225210, COSV65891270; called by muse, mutect2, varscan2
- MYH11 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 173/578 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs750935497, COSV55543687; called by muse, mutect2, varscan2
- MYH6 | c.5260G>A p.E1754K | Missense Mutation (SNP) | VAF 246/562 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372270600; called by muse, mutect2, varscan2
- MYL12A | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as COSV54182730; called by muse, mutect2, varscan2
- MYO1A | c.1428C>A p.F476L | Missense Mutation (SNP) | VAF 120/658 reads (18%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as COSV55653011; called by mutect2, varscan2
- MYO9B | c.6146C>T p.S2049L | Missense Mutation (SNP) | VAF 171/484 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.019); catalogued as rs746839076, COSV55727708; called by muse, mutect2, varscan2
- MYOC | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 124/620 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.216); catalogued as CM034257, CM990911, COSV50674382; called by muse, mutect2, varscan2
- MYOG | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 121/576 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV54096037, COSV99613979; called by muse, mutect2, varscan2
- MYPN | c.3896C>T p.S1299F | Missense Mutation (SNP) | VAF 133/353 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); catalogued as rs748628394; called by muse, mutect2, varscan2
- N6AMT1 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 157/387 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58135997; called by muse, mutect2, varscan2
- NAALADL2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV70795326; called by muse, mutect2, varscan2
- NAALADL2 | c.1291A>G p.N431D | Missense Mutation (SNP) | VAF 120/241 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1560591741; called by muse, mutect2, varscan2
- NAPEPLD | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 180/490 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs1395746306; called by muse, mutect2, varscan2
- NAV1 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 120/604 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55216008; called by muse, mutect2, varscan2
- NBEA | c.4442G>A p.R1481K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs942710194, COSV59785419; called by muse, mutect2, varscan2
- NBEA | c.4576G>A p.G1526S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767928250; called by muse, mutect2, varscan2
- NBPF12 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 30/892 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1455345088; called by muse, mutect2
- NCCRP1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 234/580 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766976562; called by muse, mutect2, varscan2
- NCOA1 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 116/374 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs778193446, COSV56044235; called by muse, mutect2, varscan2
- NDST3 | c.1070-1G>A p.X357_splice | Splice Site (SNP) | VAF 109/269 reads (41%) | catalogued as COSV99632187; called by muse, mutect2, varscan2
- NEB | c.12286G>A p.D4096N | Missense Mutation (SNP) | VAF 299/358 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375143141; called by muse, mutect2, varscan2
- NECTIN4 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 355/655 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as COSV63513528; called by muse, mutect2, varscan2
- NEFH | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 268/961 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as COSV60219804; called by muse, mutect2, varscan2
- NEK10 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 176/311 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365278073, COSV58289414; called by muse, varscan2
- NEK10 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV58284764; called by muse, mutect2, varscan2
- NELL1 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.958); catalogued as rs753194613, COSV54250718; called by muse, mutect2, varscan2
- NELL2 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61571244, COSV61571447; called by muse, mutect2, varscan2
- NEO1 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 55/469 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56071409; called by muse, mutect2, varscan2
- NEXN | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.477); catalogued as COSV53941666; called by muse, mutect2, varscan2
- NFS1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 255/659 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100931918; called by muse, mutect2, varscan2
- NIPAL4 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 166/317 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV61731181; called by muse, mutect2, varscan2
- NKD2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 226/555 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.366); catalogued as rs780433973, COSV104386118; called by muse, mutect2, varscan2
- NLRP10 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 262/531 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV60778583; called by muse, mutect2, varscan2
- NLRP12 | c.3061C>T p.R1021W | Missense Mutation (SNP) | VAF 101/592 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs774905024, COSV100146001; called by muse, mutect2, varscan2
- NLRP14 | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55070412; called by muse, mutect2, varscan2
- NLRP2 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 371/869 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs866985418; called by muse, mutect2, varscan2
- NLRP4 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 204/520 reads (39%) | catalogued as COSV56714395; called by mutect2, varscan2
- NLRP5 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 213/473 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66761986; called by muse, mutect2, varscan2
- NLRP5 | c.3594G>A p.W1198* | Nonsense Mutation (SNP) | VAF 99/378 reads (26%) | catalogued as COSV66762612; called by muse, mutect2
- NLRP7 | c.2185G>A p.G729R (on ENST00000340844 / NM_206828.3; = p.G701R on NM_139176.3) | Missense Mutation (SNP) | VAF 418/1010 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60180699; called by muse, varscan2
- NLRP9 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 242/607 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1392561462; called by muse, mutect2, varscan2
- NOS2 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 388/502 reads (77%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs369015052; called by muse, mutect2, varscan2
- NOX3 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 129/158 reads (82%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as rs181984491; called by muse, mutect2, varscan2
- NPIPB2 | c.1038G>A p.M346I (on ENST00000399147; = p.M206I on NM_001355514.1) | Missense Mutation (SNP) | VAF 432/833 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs774686849; called by muse, varscan2
- NRXN1 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 210/649 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV68016206; called by muse, mutect2, varscan2
- NUFIP1 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.638); catalogued as rs950214360; called by muse, mutect2, varscan2
- OAS1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs771818638, COSV99177085; called by muse, mutect2
- ODF3L2 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 265/715 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs763474720; called by muse, mutect2, varscan2
- OGFR | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 482/1162 reads (41%) | catalogued as rs373481743, COSV51700968; called by muse, mutect2, varscan2
- OPRK1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 133/271 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs370616732; called by muse, mutect2, varscan2
- OR10A2 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV56300782; called by muse, varscan2
- OR10A3 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 219/385 reads (57%) | SIFT tolerated (1); PolyPhen possibly damaging (0.745); catalogued as COSV100660222; called by muse, mutect2, varscan2
- OR10H3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV59944818; called by muse, mutect2, varscan2
- OR10J1 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs952346218, COSV71128695; called by muse, mutect2, varscan2
- OR10T2 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 123/225 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1212822908, COSV57782693; called by muse, mutect2, varscan2
- OR12D2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 146/189 reads (77%) | SIFT tolerated (0.32); PolyPhen benign (0.232); catalogued as COSV99058475; called by muse, mutect2, varscan2
- OR14A16 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV62927504; called by muse, mutect2, varscan2
- OR1I1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 209/516 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1369437955, COSV99264859; called by muse, mutect2, varscan2
- OR2A25 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 159/379 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1235603079, COSV68717390; called by muse, mutect2, varscan2
- OR2B11 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 120/565 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs769990807, COSV59511126; called by muse, mutect2, varscan2
- OR2B2 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 289/380 reads (76%) | catalogued as COSV100308054; called by muse, mutect2, varscan2
- OR2L13 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV63548953, COSV63549512; called by muse, mutect2, varscan2
- OR2L3 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63454596; called by muse, mutect2
- OR2T10 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 92/454 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs61730924, COSV57897325; called by muse, mutect2, varscan2
- OR2W1 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV65851468; called by muse, mutect2, varscan2
- OR3A2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 139/298 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV101375096; called by muse, mutect2, varscan2
- OR3A3 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 187/223 reads (84%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs375267018; called by muse, mutect2, varscan2
- OR4K1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 92/228 reads (40%) | catalogued as COSV99579151; called by muse, mutect2
- OR4K1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs764753465, COSV53461869; called by muse, varscan2
- OR4K5 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60002438; called by muse, mutect2, varscan2
- OR4Q3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV104404868, COSV59177839, COSV99045369; called by muse, varscan2
- OR4S1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 271/366 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369830806, COSV60679044, COSV60679094; called by muse, mutect2, varscan2
- OR51B4 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 105/189 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs1388514726; called by muse, mutect2, varscan2
- OR51G1 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.317); catalogued as COSV58969324, COSV58969611; called by muse, mutect2, varscan2
- OR51G1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); catalogued as COSV100429417; called by muse, mutect2, varscan2
- OR51M1 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100150122; called by muse, mutect2, varscan2
- OR52L1 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 180/306 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV59986997; called by muse, mutect2, varscan2
- OR52M1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1355303861, COSV64173146; called by muse, mutect2, varscan2
- OR5A2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 104/146 reads (71%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.841); catalogued as rs774409327, COSV57391194; called by muse, mutect2, varscan2
- OR5P2 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as rs142490724, COSV61490067; called by muse, mutect2, varscan2
- OR6C74 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1421216370; called by muse, mutect2, varscan2
- OR6T1 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 196/282 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745859372; called by muse, mutect2, varscan2
- OR8A1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 116/168 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1267640256; called by muse, mutect2, varscan2
- OR8J2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 123/177 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746426170; called by muse, varscan2
- OR8K5 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 120/157 reads (76%) | catalogued as rs147577134, COSV57889485; called by muse, mutect2, varscan2
- OSBPL8 | c.1373C>A p.P458H | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV53878595; called by muse, mutect2, varscan2
- OTOG | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 142/543 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as rs541019060; called by muse, mutect2, varscan2
- OTOGL | c.4048G>A p.E1350K (on ENST00000547103; = p.E1341K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV72007005; called by muse, mutect2, varscan2
- OTOGL | c.4199C>T p.P1400L (on ENST00000547103; = p.P1391L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs754094747, COSV101509046; called by muse, mutect2, varscan2
- OXGR1 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 90/286 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs1267529617; called by muse, mutect2, varscan2
- P2RY14 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 188/371 reads (51%) | catalogued as COSV99854478; called by muse, mutect2, varscan2
- PALD1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 161/430 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54977306; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2084C>T p.S695F (on ENST00000259318 / NM_001136562.3; = p.S926F on NM_007203.5) | Missense Mutation (SNP) | VAF 230/315 reads (73%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1382175783; called by muse, mutect2, varscan2
- PAPPA | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 206/311 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60280755; called by muse, mutect2, varscan2
- PAPPA2 | c.4483C>T p.P1495S | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV62799263; called by muse, mutect2, varscan2
- PARD3B | c.2450C>T p.A817V (on ENST00000406610 / NM_001302769.2; = p.A748V on NM_057177.7) | Missense Mutation (SNP) | VAF 271/326 reads (83%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1229083820; called by muse, mutect2, varscan2
- PARVA | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 80/379 reads (21%) | catalogued as COSV58512485; called by muse, mutect2, varscan2
- PARVB | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 284/1124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1345336192; called by muse, mutect2
- PBX4 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 339/740 reads (46%) | catalogued as COSV99232441; called by muse, mutect2, varscan2
- PCBP3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 246/624 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1338453281; called by muse, mutect2, varscan2
- PCDH15 | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs763848274, COSV64675461; called by muse, mutect2, varscan2
- PCDH15 | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs909968793; called by muse, mutect2, varscan2
- PCDH17 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 142/465 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV100931377; called by muse, mutect2, varscan2
- PCDHA1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 257/543 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as rs782000737; called by muse, mutect2
- PCDHA11 | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 147/556 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56517237; called by muse, mutect2, varscan2
- PCDHA2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 226/806 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs1210282107; called by muse, mutect2, varscan2
- PCDHA2 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 216/435 reads (50%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.071); catalogued as COSV65365653; called by muse, mutect2, varscan2
- PCDHA6 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 117/436 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as COSV65342295; called by muse, mutect2, varscan2
- PCDHA8 | c.2270G>A p.R757K | Missense Mutation (SNP) | VAF 124/520 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs782706533; called by muse, mutect2, varscan2
- PCDHB10 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 39/500 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.33); catalogued as rs781915643, COSV53377297; called by muse, mutect2
- PCDHB12 | c.2153G>A p.R718K | Missense Mutation (SNP) | VAF 327/706 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.418); catalogued as COSV53399345; called by muse, mutect2, varscan2
- PCDHB15 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 349/709 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV50858209; called by muse, mutect2, varscan2
- PCDHB2 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 102/848 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.248); catalogued as rs782035707, COSV50566884; called by muse, varscan2
- PCDHB8 | c.2153G>A p.S718N | Missense Mutation (SNP) | VAF 164/696 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs782663746; called by muse, varscan2
- PCDHGA6 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 155/475 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.124); catalogued as COSV54010962; called by muse, mutect2, varscan2
- PCLO | c.15226C>T p.R5076* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV61623463; called by muse, mutect2, varscan2
- PCLO | c.12988C>T p.H4330Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.905); catalogued as rs953489035; called by muse, mutect2, varscan2
- PCLO | c.3769C>T p.P1257S | Missense Mutation (SNP) | VAF 154/376 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1411607739; called by muse, mutect2, varscan2
- PCLO | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 145/347 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.654); catalogued as rs1278660961, COSV100426272, COSV61660317; called by muse, mutect2, varscan2
- PCNX1 | c.3715C>T p.P1239S | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.644); catalogued as rs745432262; called by muse, mutect2, varscan2
- PCSK9 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 144/670 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs770080583; called by muse, varscan2
- PDE4DIP | c.6785C>T p.T2262I | Missense Mutation (SNP) | VAF 271/567 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs782168860; called by muse, varscan2
- PDLIM2 | c.776C>T p.A259V (on ENST00000397760; = p.A509V on NM_021630.6) | Missense Mutation (SNP) | VAF 254/529 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1465723868; called by muse, mutect2, varscan2
- PENK | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 208/586 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as rs1563485661; called by muse, mutect2, varscan2
- PHEX | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 151/177 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65074803; called by muse, mutect2, varscan2
- PHKA2 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 284/346 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101177474; called by muse, mutect2, varscan2
- PID1 | c.392C>T p.P131L (on ENST00000354069 / NM_001330156.1; = p.P129L on NM_017933.5) | Missense Mutation (SNP) | VAF 384/476 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs200100687, COSV62473176; called by muse, mutect2, varscan2
- PIEZO2 | c.8152C>T p.R2718* | Nonsense Mutation (SNP) | VAF 129/337 reads (38%) | catalogued as rs753034565, COSV53286887, COSV53291478; called by muse, mutect2, varscan2
- PIGR | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 244/391 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0.121); catalogued as rs549356645; called by muse, mutect2, varscan2
- PIK3C2B | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 98/562 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.476); catalogued as rs530979365; called by muse, mutect2, varscan2
- PIK3C2B | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 379/638 reads (59%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs61757717, COSV65804027; called by muse, mutect2, varscan2
- PIK3R2 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 289/681 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55849946, COSV55850165; called by muse, mutect2, varscan2
- PKHD1L1 | c.5536G>A p.G1846R | Missense Mutation (SNP) | VAF 105/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007097; called by muse, mutect2, varscan2
- PKP3 | c.2318A>G p.N773S | Missense Mutation (SNP) | VAF 140/641 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs780909417; called by muse, mutect2, varscan2
- PLA2G2D | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 217/512 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111517474; called by muse, mutect2, varscan2
- PLCE1 | c.2013G>A p.M671I | Missense Mutation (SNP) | VAF 216/550 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1229744391; called by muse, mutect2, varscan2
- PLCE1 | c.5809C>T p.R1937C | Missense Mutation (SNP) | VAF 144/330 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53343491; called by muse, mutect2, varscan2
- PLCH1 | c.542G>A p.R181K (on ENST00000340059 / NM_001130960.2; = p.R193K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/202 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV100397502, COSV58210074; called by muse, mutect2, varscan2
- PLCL1 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 170/207 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101406800; called by muse, mutect2, varscan2
- PLCXD3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs182360912, COSV60606280; called by muse, mutect2, varscan2
- PLCZ1 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs749285005, COSV56854152; called by muse, mutect2, varscan2
- PLCZ1 | c.569+1G>A p.X190_splice | Splice Site (SNP) | VAF 34/83 reads (41%) | catalogued as rs745455459; called by muse, mutect2, varscan2
- PLEC | c.6731C>T p.S2244F (on ENST00000322810 / NM_201380.4; = p.S2134F on NM_000445.5) | Missense Mutation (SNP) | VAF 397/1231 reads (32%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.03); catalogued as rs782287448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLG | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 137/200 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as rs1005986976, COSV51980630; called by muse, mutect2, varscan2
- PLG | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99804779; called by muse, mutect2, varscan2
- PLSCR2 | c.831G>A p.M277I (on ENST00000497985 / NM_001199978.1; = p.M204I on NM_020359.2) | Missense Mutation (SNP) | VAF 168/311 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.053); catalogued as rs1484328258, COSV100367851; called by muse, mutect2, varscan2
- PNLDC1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 215/295 reads (73%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs781459190, COSV99277715, COSV99278042; called by muse, mutect2
- PNMA8A | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 225/600 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748105308; called by muse, mutect2, varscan2
- PNPLA1 | c.1274C>T p.P425L (on ENST00000394571 / NM_001374623.1; = p.P330L on NM_173676.2) | Missense Mutation (SNP) | VAF 404/507 reads (80%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV57238058; called by muse, mutect2, varscan2
- PNPT1 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 256/541 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775717775, COSV53176279; called by muse, mutect2, varscan2
- PODNL1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 141/390 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV54308332; called by muse, mutect2, varscan2
- POM121L12 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 296/770 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.148); catalogued as COSV101374887, COSV68693476; called by muse, mutect2, varscan2
- PON1 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs185623242; called by muse, mutect2, varscan2
- PPEF2 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 165/497 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54420366, COSV54422075; called by muse, mutect2, varscan2
- PPFIA2 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61025029, COSV61026721, COSV99048581; called by muse, mutect2, varscan2
- PPID | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 213/556 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs760272453; called by muse, mutect2, varscan2
- PPL | c.4441G>A p.E1481K | Missense Mutation (SNP) | VAF 398/798 reads (50%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.915); catalogued as rs148764760; called by muse, mutect2, varscan2
- PPP1R16B | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 323/753 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs759069655, COSV100239791, COSV55378017; called by muse, mutect2, varscan2
- PPP1R3A | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.854); catalogued as rs780147047, COSV99494662; called by muse, mutect2, varscan2
- PPP1R3A | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52881558; called by muse, varscan2
- PPP1R3A | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52894643; called by muse, varscan2
- PRAMEF11 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 316/548 reads (58%) | catalogued as COSV101463301; called by muse, mutect2, varscan2
- PRAMEF4 | c.1161C>A p.F387L | Missense Mutation (SNP) | VAF 190/768 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.05); catalogued as rs1440866467, COSV52441102; called by muse, varscan2
- PRDM16 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 349/1309 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV54579632; called by muse, mutect2, varscan2
- PRDM9 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 123/375 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57004725, COSV57013024; called by muse, mutect2, varscan2
- PRICKLE1 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 231/427 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs150766064, COSV58208901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCB | c.1950G>A p.M650I | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.142); catalogued as rs866828752; called by muse, mutect2, varscan2
- PRKG1 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1405161119; called by muse, mutect2, varscan2
- PROKR1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 128/365 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs776381814, COSV58139376; called by muse, mutect2, varscan2
- PRPSAP2 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 230/298 reads (77%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.523); catalogued as rs750128219, COSV52064605; called by muse, mutect2, varscan2
- PRR12 | c.1997C>T p.P666L (on ENST00000615927; = p.P1487L on NM_020719.3) | Missense Mutation (SNP) | VAF 319/832 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs373218764; called by muse, mutect2, varscan2
- PRR23B | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 377/754 reads (50%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as rs1394629876; called by muse, mutect2, varscan2
- PRRT4 | c.2257G>A p.E753K (on ENST00000446477 / NM_001174164.1; = p.R408Q on NM_001114726.3) | Missense Mutation (SNP) | VAF 403/919 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs1303109208; called by muse, mutect2, varscan2
- PRRT4 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 202/524 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.05); catalogued as rs1333945662; called by muse, mutect2, varscan2
- PRTG | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 136/459 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs201047603; called by muse, mutect2, varscan2
- PRUNE2 | c.4580C>T p.S1527L | Missense Mutation (SNP) | VAF 123/180 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs773882315, COSV65038307; called by muse, mutect2, varscan2
- PSD | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 219/643 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV50048448; called by muse, varscan2
- PSG4 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 115/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745631140; called by muse, mutect2, varscan2
- PSKH2 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 135/435 reads (31%) | catalogued as rs772210187, COSV52610940; called by muse, mutect2, varscan2
- PSTPIP2 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs1319638480, COSV68444054; called by muse, mutect2, varscan2
- PTBP3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 195/283 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99270420; called by muse, mutect2, varscan2
- PTCHD4 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 123/477 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs765780501, COSV59799349; called by muse, mutect2, varscan2
- PTPN23 | c.3979G>A p.E1327K | Missense Mutation (SNP) | VAF 468/786 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as rs759389182, COSV55546032; called by muse, mutect2, varscan2
- PTPRB | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 102/348 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV54248838, COSV54253544; called by muse, mutect2, varscan2
- PTPRE | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 175/437 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs772328329; called by muse, mutect2, varscan2
- PTPRN2 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 272/764 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67039045; called by muse, mutect2
- PURG | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 345/684 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs7464560; called by muse, varscan2
- PXDNL | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 84/285 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs75168301; called by muse, mutect2, varscan2
- PYGO2 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 303/914 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs1477315837, COSV63756577, COSV63757477; called by muse, mutect2, varscan2
- RALGPS1 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 198/280 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1349447487; called by muse, mutect2, varscan2
- RAPGEF5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 123/281 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as rs1349966794; called by muse, mutect2, varscan2
- RAPH1 | c.3740C>T p.S1247F | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV55583533; called by muse, mutect2, varscan2
- RASGRP3 | c.1655C>T p.S552F (on ENST00000402538 / NM_001349975.2; = p.S551F on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 209/658 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369940541; called by muse, mutect2, varscan2
- RASGRP4 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 92/604 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs376620042; called by muse, mutect2, varscan2
- RBM10 | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 357/412 reads (87%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.668); catalogued as rs1556779216; called by muse, mutect2, varscan2
- RBM46 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 114/296 reads (39%) | catalogued as rs866164836, COSV55977357; called by muse, mutect2, varscan2
- RBM48 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 164/394 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as rs923207571; called by muse, mutect2
- RBMXL3 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 516/605 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1259652832, COSV57757184; called by muse, mutect2, varscan2
2,539 further variants in this file (1,339 protein-altering or splice-affecting, 1,087 silent, 113 other) are not listed here.
